Somatic mutation profile of tumor specimen 4e766d9f-ede3-4311-bf09-b1f9ba (aliquot 4e766d9f-ede3-4311-bf09-b1f9ba_D6_1) from CPTAC case 11BR038, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 47.1 years (17,215 days).
Specimen 4e766d9f-ede3-4311-bf09-b1f9ba: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f5d5d64-0570-480c-9a26-3ad122c2b427.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 6386a31e-1ecc-4229-9f0d-e09e01 (Blood Derived Normal), aliquot 6386a31e-1ecc-4229-9f0d-e09e01_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e2364a0-b113-49c6-9937-2e423399738a

The open-access MAF lists 49 somatic variants for this specimen: 31 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 13, Intron 2, Nonsense Mutation 2, Splice Site 2, RNA 2, In Frame Del 1, 5'UTR 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.372C>A p.C124* | Nonsense Mutation (SNP) | VAF 24/172 reads (14%) | catalogued as rs1555526478, CM1210346, COSV52731101, COSV52944837; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COG1 | c.1513A>G p.M505V | Missense Mutation (SNP) | VAF 114/511 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.323); catalogued as rs543395876; called by muse, mutect2, varscan2
- COL4A3 | c.3209C>T p.T1070M | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as rs373628122, COSV59257642; called by muse, mutect2
- CRIP2 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 13/213 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61274261; called by muse, mutect2
- CTU2 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs1429010154, COSV56333971; called by muse, mutect2
- IQSEC2 | c.2144C>T p.S715F (on ENST00000642864 / NM_001111125.3; = p.S510F on NM_015075.2) | Missense Mutation (SNP) | VAF 14/349 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV64725411; called by muse, mutect2
- MCCC2 | c.671C>G p.P224R | Missense Mutation (SNP) | VAF 41/306 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as CM125728; called by muse, mutect2, varscan2
- NEB | c.10777G>A p.D3593N | Missense Mutation (SNP) | VAF 44/448 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs758723038, COSV50885549; called by muse, mutect2
- PDHA1 | c.893G>C p.G298A | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM119794; called by muse, mutect2
- PGK1 | c.11C>G p.S4C | Missense Mutation (SNP) | VAF 16/494 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV64832440; called by muse, mutect2
- SUPT6H | c.1878+1G>A p.X626_splice | Splice Site (SNP) | VAF 51/313 reads (16%) | catalogued as rs760617358; called by muse, mutect2, varscan2
- ZNF790 | c.1427G>C p.R476T | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as COSV100764860, COSV63212405; called by muse, mutect2
- ADSS1 | c.1322-3C>G | Splice Region (SNP) | VAF 8/93 reads (9%) | called by muse, mutect2
- AKAP13 | c.377C>G p.S126C | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2
- ARL5C | c.508_509del p.Q170Vfs*9 | Frame Shift Del (DEL) | VAF 83/818 reads (10%) | called by mutect2, pindel, varscan2
- ARNTL | c.1664C>T p.S555L (on ENST00000403290 / NM_001297719.2; = p.S554L on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.011); called by muse, mutect2
- CLTCL1 | c.3302G>C p.R1101T | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); called by muse, mutect2
- CPNE2 | c.242T>G p.L81R | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); called by muse, mutect2
- CRIP2 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 37/435 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- DNAJC25-GNG10 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- GFM1 | c.1381-1G>C p.X461_splice | Splice Site (SNP) | VAF 8/242 reads (3%) | called by muse, mutect2
- MDGA2 | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- MEN1 | c.1740C>G p.I580M | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MYO7B | c.5044C>A p.P1682T | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OGDHL | c.2639C>A p.A880D | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLB1 | c.4346C>T p.P1449L | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLCD3 | c.2071G>A p.E691K | Missense Mutation (SNP) | VAF 14/267 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- PSME4 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- TNFAIP1 | c.743A>G p.E248G | Missense Mutation (SNP) | VAF 32/534 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- TOMM6 | c.136_144del p.I46_N48del | In Frame Del (DEL) | VAF 35/208 reads (17%) | called by mutect2, varscan2
- ZSCAN29 | c.1872A>T p.K624N | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ATG2A | c.3087C>T p.T1029= | Silent (SNP) | VAF 85/460 reads (18%) | catalogued as rs757369907; called by muse, mutect2, varscan2
- HERC1 | c.3378G>T p.L1126= | Silent (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2
- MLLT6 | c.681G>A p.Q227= | Silent (SNP) | VAF 14/445 reads (3%) | called by muse, mutect2
- MMP9 | c.1881C>T p.F627= | Silent (SNP) | VAF 6/51 reads (12%) | called by mutect2, varscan2
- OR2H1 | c.675G>A p.R225= | Silent (SNP) | VAF 47/343 reads (14%) | called by muse, mutect2, varscan2
- PRDM9 | c.1599C>T p.F533= | Silent (SNP) | VAF 54/488 reads (11%) | called by mutect2, varscan2
- PRSS1 | c.213G>A p.V71= | Silent (SNP) | VAF 18/530 reads (3%) | catalogued as COSV61197139; called by muse, mutect2
- RAD23A | c.1068G>A p.L356= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as rs1338497991; called by muse, mutect2
- SDK1 | c.4167G>C p.V1389= | Silent (SNP) | VAF 11/286 reads (4%) | called by muse, mutect2
- SHC3 | c.1734C>T p.V578= | Silent (SNP) | VAF 12/90 reads (13%) | called by muse, mutect2
- SLC38A1 | c.1107G>A p.P369= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs367890226, COSV101284194, COSV67063996; called by muse, mutect2, varscan2
- TMEM154 | c.54C>G p.P18= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as rs747637170; called by muse, mutect2, varscan2
- WIPF2 | c.1206C>T p.F402= | Silent (SNP) | VAF 18/154 reads (12%) | called by muse, mutect2, varscan2
- COX16 | c.-10G>A | 5'UTR (SNP) | VAF 21/124 reads (17%) | called by muse, mutect2, varscan2
- DNAI3 | c.1048+198C>G | Intron (SNP) | VAF 13/175 reads (7%) | catalogued as rs1275971295; called by muse, mutect2
- HNF1B | c.1045+20C>G | Intron (SNP) | VAF 70/672 reads (10%) | called by muse, mutect2, varscan2
- OR7A2P | n.472C>G | RNA (SNP) | VAF 11/210 reads (5%) | called by muse, mutect2
- SPATA31C2 | n.1430C>A | RNA (SNP) | VAF 107/614 reads (17%) | called by muse, mutect2, varscan2
